Somatic mutation profile of tumor specimen TCGA-29-1688-01A (aliquot TCGA-29-1688-01A-01W-0633-09) from TCGA case TCGA-29-1688, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 39.9 years (14,574 days).
Specimen TCGA-29-1688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98581bd6-1279-405e-a739-e6ce883dca89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1688-10A (Blood Derived Normal), aliquot TCGA-29-1688-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f0e9d77-c78a-47ac-b4e2-e26e98a2c129

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 3, Frame Shift Del 1, In Frame Del 1, Intron 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 50/68 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAM12 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64108668; called by muse, mutect2, varscan2
- ARHGAP4 | c.1095C>G p.I365M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100603968; called by muse, mutect2
- ATG2B | c.4019C>G p.S1340C | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166367011, COSV99952010; called by muse, mutect2
- B4GALT5 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 8/176 reads (5%) | catalogued as COSV100866972; called by muse, mutect2
- BCAP31 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998971015, COSV61451800; called by muse, mutect2, varscan2
- C10orf71 | c.984G>C p.Q328H | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100110000; called by muse, mutect2
- C2orf80 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs199911442, COSV58017318; called by muse, mutect2, varscan2
- CCDC159 | c.492A>C p.Q164H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV52260665; called by muse, mutect2, varscan2
- CFAP65 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55390697; called by muse, mutect2, varscan2
- COL6A3 | c.4919T>C p.I1640T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV55094325; called by muse, mutect2, varscan2
- GAB4 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as rs750376591, COSV68754178; called by muse, mutect2, varscan2
- HDC | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143418383; called by muse, mutect2, varscan2
- HSP90B1 | c.1271A>T p.D424V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55356142; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.77); catalogued as rs751827217, COSV61155639, COSV61168151; called by muse, mutect2, varscan2
- KCNH1 | c.1816G>A p.D606N (on ENST00000271751 / NM_172362.3; = p.D579N on NM_002238.4) | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV55087273; called by muse, mutect2, varscan2
- KRTAP5-5 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs80015637, COSV68785187; called by muse, varscan2
- LMBR1 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.721); catalogued as COSV62221096; called by muse, mutect2, varscan2
- LRP1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV99675375; called by muse, mutect2
- MOCOS | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54344659; called by muse, mutect2, varscan2
- MYH4 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99700888; called by muse, mutect2
- NFRKB | c.3862A>T p.T1288S (on ENST00000446488 / NM_001143835.2; = p.T1313S on NM_006165.3) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.368); catalogued as COSV99859292; called by muse, mutect2
- NIPSNAP1 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV53342917; called by muse, mutect2, varscan2
- NOL11 | c.1527G>T p.L509F | Missense Mutation (SNP) | VAF 171/210 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs766235239, COSV53521941, COSV53523966; called by muse, mutect2, varscan2
- OTOGL | c.747T>A p.H249Q (on ENST00000547103; = p.H240Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs370581575; called by muse, mutect2, varscan2
- P4HTM | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV59087671; called by muse, mutect2, varscan2
- PTPN3 | c.469C>G p.H157D | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV99355594; called by muse, mutect2
- RASL11A | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV54081327, COSV99611047; called by muse, mutect2
- RNF32 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs576205900, COSV58732013; called by muse, mutect2, varscan2
- SLC7A3 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53227923; called by muse, mutect2, varscan2
- SLITRK4 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as COSV62024620; called by muse, mutect2, varscan2
- SPATA18 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.644); catalogued as COSV54646032; called by muse, mutect2, varscan2
- SPG11 | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55996860; called by muse, mutect2, varscan2
- SULF2 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63417244; called by muse, mutect2, varscan2
- TACC2 | c.2347dup p.Q783Pfs*45 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | catalogued as rs750901207; called by mutect2, varscan2
- TRIM58 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 203/889 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192337108, COSV63570837; called by muse, mutect2, varscan2
- UACA | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs373823406; called by muse, mutect2, varscan2
- VCP | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV62721019; called by muse, mutect2, varscan2
- ZFP36 | c.80C>A p.S27Y (on ENST00000594442; = p.S21Y on NM_003407.5) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV50528814; called by muse, mutect2, varscan2
- ZNF260 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 14/186 reads (8%) | catalogued as COSV101591044; called by muse, mutect2
- ZNF75D | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV100883618, COSV66133410; called by muse, mutect2
- CD109 | c.247+2dup p.X83_splice | Splice Site (INS) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- OR2G6 | c.161_174del p.R54Nfs*29 | Frame Shift Del (DEL) | VAF 84/490 reads (17%) | called by mutect2, pindel, varscan2
- PSMD14 | c.28_39del p.G10_G13del | In Frame Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ELP1 | c.3642G>A p.E1214= | Silent (SNP) | VAF 59/220 reads (27%) | catalogued as rs748018304, COSV65898298; called by muse, mutect2, varscan2
- HIVEP3 | c.2757G>A p.E919= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as COSV99912127; called by muse, mutect2, varscan2
- ITPKB | c.1260C>T p.S420= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs775226885, COSV55263803; called by muse, mutect2, varscan2
- LOXL4 | c.1096C>T p.L366= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs762223261, COSV53257383; called by muse, mutect2, varscan2
- POGZ | c.804G>A p.G268= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV99652584; called by muse, mutect2
- SLC9A6 | c.1425G>T p.R475= | Silent (SNP) | VAF 81/170 reads (48%) | catalogued as COSV65788264; called by muse, mutect2, varscan2
- SORCS3 | c.1563C>A p.G521= | Silent (SNP) | VAF 15/165 reads (9%) | catalogued as COSV100864950; called by muse, mutect2
- TCERG1 | c.1260A>G p.A420= | Silent (SNP) | VAF 137/286 reads (48%) | catalogued as COSV57038481; called by muse, mutect2, varscan2
- TFIP11 | c.1833C>T p.N611= | Silent (SNP) | VAF 164/400 reads (41%) | catalogued as COSV53226526; called by muse, varscan2
- ZFPM2 | c.1539T>C p.A513= | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as COSV101023135; called by muse, mutect2
- ZMIZ2 | c.2031G>A p.T677= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1430538542, COSV54809018; called by muse, mutect2, varscan2
- ZNF609 | c.402G>A p.L134= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV58585308; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845511 G>A | 5'Flank (SNP) | VAF 27/112 reads (24%) | catalogued as rs1312789607; called by muse, mutect2, varscan2
- NRP2 | c.2440+9702C>G | Intron (SNP) | VAF 59/242 reads (24%) | catalogued as COSV55930285; called by muse, mutect2, varscan2
